Somatic mutation profile of tumor specimen TCGA-FD-A5BX-01A (aliquot TCGA-FD-A5BX-01A-11D-A26M-08) from TCGA case TCGA-FD-A5BX, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 82.9 years (30,276 days).
Specimen TCGA-FD-A5BX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c267edc3-c546-464b-80cc-e72a8d3dd227.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A5BX-10A (Blood Derived Normal), aliquot TCGA-FD-A5BX-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a750138-af56-4b31-bc7c-980673d82f40

The open-access MAF lists 384 somatic variants for this specimen: 287 protein-altering or splice-affecting, 91 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 254, Silent 91, Nonsense Mutation 23, Splice Site 3, Splice Region 3, In Frame Del 2, 5'UTR 2, RNA 2, Nonstop Mutation 1, Intron 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 30/61 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as rs1064793732, CM126690, COSV55881636, COSV55977337; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RXRA | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 49/90 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SRD5A3 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772795484, COSV51711296; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.2176G>C p.D726H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52194979, COSV52214022; called by muse, mutect2, varscan2
- ABCB11 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55585843; called by muse, mutect2, varscan2
- ABCF3 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV53047126; called by muse, mutect2, varscan2
- ABHD16A | c.1312C>G p.P438A | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as COSV65451380; called by muse, mutect2, varscan2
- ABHD16A | c.917C>A p.S306* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV101013396; called by muse, mutect2, varscan2
- ABHD16A | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.403); catalogued as COSV65451388; called by muse, mutect2, varscan2
- ABR | c.1535C>G p.S512C (on ENST00000302538 / NM_021962.5; = p.S475C on NM_001092.5) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52140973, COSV52143706; called by muse, mutect2, varscan2
- ACTA2 | c.736G>C p.D246H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56515692; called by muse, mutect2, varscan2
- ACTN2 | c.2134C>A p.H712N | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV63972215; called by muse, mutect2, varscan2
- ADAM20 | c.1582C>G p.Q528E | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV56454135; called by muse, mutect2, varscan2
- ADAMTS16 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as rs1315627534, COSV99943449; called by muse, mutect2, varscan2
- ADCY8 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV53894881, COSV53907491, COSV53918807; called by muse, mutect2, varscan2
- ADH1B | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 79/285 reads (28%) | catalogued as COSV100520894; called by muse, mutect2, varscan2
- AGGF1 | c.533_538del p.L178_T180delinsS | In Frame Del (DEL) | VAF 11/49 reads (22%) | catalogued as COSV57227831; called by mutect2, pindel, varscan2
- AKAP4 | c.771C>A p.N257K | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs781918688, COSV62073761; called by muse, mutect2, varscan2
- AKR1E2 | c.777G>T p.Q259H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53629664, COSV53631548; called by muse, mutect2, varscan2
- ALDH1A2 | c.939C>G p.F313L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV51078291; called by muse, mutect2, varscan2
- AMIGO3 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs777353932, COSV57537600; called by muse, mutect2, varscan2
- AMOTL2 | c.1713G>C p.Q571H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51437810; called by muse, mutect2, varscan2
- AMZ2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV63082542, COSV63082823; called by muse, mutect2, varscan2
- ANAPC5 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99946540, COSV99946571; called by muse, mutect2, varscan2
- ANP32D | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV56980026, COSV56980054, COSV56980118; called by muse, mutect2, varscan2
- AOC1 | c.1660C>G p.L554V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as rs771806799, COSV62866966; called by mutect2, varscan2
- AP1G2 | c.299C>A p.A100D | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV100436775, COSV58110372; called by muse, mutect2, varscan2
- ARHGEF2 | c.1565C>T p.S522L (on ENST00000361247 / NM_001162383.2; = p.S494L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs756219943, COSV58106853; called by muse, mutect2, varscan2
- ATP8B1 | c.3730G>A p.E1244K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as COSV52173211; called by muse, mutect2, varscan2
- BARD1 | c.1319A>G p.D440G | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753446928, COSV53609052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BBS2 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as rs775577429, COSV55325201; called by muse, mutect2, varscan2
- BICRAL | c.2063G>C p.G688A | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as COSV58403645; called by muse, varscan2
- C10orf90 | c.2083C>G p.Q695E | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV52949848; called by muse, mutect2, varscan2
- C11orf65 | c.503G>C p.R168T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67596846, COSV67597315; called by muse, mutect2, varscan2
- C1orf141 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV63992172; called by muse, mutect2, varscan2
- C2orf78 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV68516413; called by muse, mutect2, varscan2
- CBARP | c.403G>A p.E135K (on ENST00000382477; = p.E141K on NM_152769.3) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV53067709; called by muse, mutect2, varscan2
- CBFA2T2 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100656489; called by muse, mutect2, varscan2
- CCDC130 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV99237926; called by muse, mutect2, varscan2
- CCDC144A | c.811C>T p.H271Y | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.183); catalogued as rs200353361; called by muse, mutect2, varscan2
- CDH12 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1033367087, COSV66389351; called by muse, mutect2, varscan2
- CDH4 | c.2278G>C p.E760Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV100849491, COSV64642874; called by muse, mutect2, varscan2
- CDK17 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.517); catalogued as COSV54126764; called by muse, mutect2, varscan2
- CEACAM4 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs782266854, COSV55730713; called by muse, mutect2, varscan2
- CELSR2 | c.6889G>T p.A2297S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as rs895973339, COSV54767233; called by muse, mutect2, varscan2
- CETN3 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51616839; called by muse, mutect2, varscan2
- CFAP20DC | c.1378G>C p.E460Q (on ENST00000482387 / NM_001351530.2; = p.E335Q on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs752788408, COSV55916476; called by muse, mutect2, varscan2
- CFAP61 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as COSV55620244; called by muse, mutect2, varscan2
- CHERP | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52222521; called by muse, mutect2, varscan2
- CLDN16 | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV53226964; called by muse, mutect2, varscan2
- CLEC16A | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1381075901, COSV68498052; called by muse, mutect2, varscan2
- CLTC | c.4448C>T p.S1483L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52245089; called by mutect2, varscan2
- CRYBG1 | c.2193G>C p.K731N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64810845; called by muse, mutect2, varscan2
- CSMD2 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.738); catalogued as COSV53882759, COSV53950992; called by muse, mutect2, varscan2
- CTSF | c.727_729del p.E243del | In Frame Del (DEL) | VAF 18/93 reads (19%) | catalogued as rs769735423; called by pindel, varscan2
- CYP26B1 | c.985C>G p.H329D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV50010814; called by muse, mutect2, varscan2
- CYP2B6 | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57842576; called by muse, mutect2, varscan2
- CYP3A4 | c.1516C>G p.L506V (on ENST00000336411; = p.L475V on NM_017460.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as CM1412652, COSV60501021; called by muse, mutect2, varscan2
- DCAF11 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1292003207, COSV58108305; called by muse, mutect2, varscan2
- DDHD1 | c.960C>G p.F320L (on ENST00000323669; = p.F517L on NM_030637.3) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60357451, COSV60358418; called by muse, mutect2, varscan2
- DDX20 | c.257C>G p.S86W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63831292; called by mutect2, varscan2
- DDX4 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV61753599; called by muse, mutect2, varscan2
- DENND5B | c.3793G>C p.E1265Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60900019; called by muse, mutect2, varscan2
- DEPDC1B | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV54008152, COSV54014017; called by muse, mutect2, varscan2
- DGKA | c.1080G>C p.L360F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs772027345, COSV59384265; called by muse, varscan2
- DGKA | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.449); catalogued as rs757427814, COSV59384270; called by muse, varscan2
- DHX15 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as COSV61025759; called by muse, mutect2, varscan2
- DMXL2 | c.6316G>C p.E2106Q | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV51841182; called by muse, mutect2, varscan2
- DNAH17 | c.264C>G p.N88K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV67750053; called by muse, mutect2, varscan2
- DNAH9 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV52335519; called by muse, mutect2, varscan2
- DNAJC2 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV50789564, COSV50791643; called by muse, mutect2, varscan2
- DPYSL4 | c.813G>A p.G271= | Splice Region (SNP) | VAF 16/61 reads (26%) | catalogued as COSV58306000; called by muse, mutect2
- DUSP6 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.661); catalogued as COSV99683971; called by muse, mutect2, varscan2
- DZIP1L | c.1745C>T p.S582F | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV59519325; called by muse, mutect2, varscan2
- EFS | c.1168G>C p.D390H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767796757, COSV53731240; called by muse, mutect2, varscan2
- ELANE | c.104G>C p.R35P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV52255082; called by muse, mutect2, varscan2
- EML1 | c.2300C>T p.S767L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV51741359; called by muse, mutect2, varscan2
- ENDOV | c.687G>T p.R229S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs374434149; called by muse, varscan2
- ENTPD8 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100395772; called by muse, mutect2
- EPHA2 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV64452179; called by muse, mutect2, varscan2
- EPHA5 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.804); catalogued as rs907860171, COSV104385040, COSV56632471; called by muse, mutect2, varscan2
- ESPN | c.1407C>G p.I469M | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.885); catalogued as COSV64703796; called by muse, mutect2, varscan2
- EWSR1 | c.1391G>C p.R464T | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.95); catalogued as COSV58421682, COSV58424807; called by muse, mutect2, varscan2
- EXOC3L4 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV66295302; called by muse, mutect2, varscan2
- FAM193A | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs749558129, COSV61191106; called by muse, mutect2, varscan2
- FLG2 | c.5966C>G p.S1989* | Nonsense Mutation (SNP) | VAF 78/255 reads (31%) | catalogued as COSV101166295; called by muse, mutect2, varscan2
- FLII | c.2619G>T p.M873I | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.017); catalogued as COSV57496367, COSV57496600; called by muse, mutect2, varscan2
- FNBP1L | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53091559; called by muse, mutect2, varscan2
- FRMD4A | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV52715456, COSV99198613; called by muse, mutect2, varscan2
- GDF5 | c.1062C>G p.F354L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV65499557, COSV65500251; called by muse, mutect2, varscan2
- GJB2 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67010518; called by muse, mutect2
- GON4L | c.5312C>G p.S1771C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV55187535; called by muse, varscan2
- GRIP2 | c.793G>A p.E265K (on ENST00000619221; = p.E168K on NM_001080423.4) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV56119818, COSV56119866; called by muse, mutect2, varscan2
- GRM2 | c.735G>C p.M245I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as COSV56583279; called by muse, mutect2, varscan2
- GTF2F1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775027102, COSV66725013; called by muse, mutect2, varscan2
- GTPBP8 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV55605881; called by muse, mutect2, varscan2
- HECTD2 | c.834G>C p.K278N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV53218966; called by muse, varscan2
- HERC5 | c.1816G>C p.E606Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV52037447; called by muse, mutect2, varscan2
- HERPUD2 | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV60943973; called by muse, mutect2, varscan2
- HK2 | c.2226G>T p.E742D | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51873467; called by muse, mutect2, varscan2
- HOXB2 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100344829, COSV57485898; called by muse, mutect2, varscan2
- HPGDS | c.296T>A p.M99K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.506); catalogued as COSV54773068; called by muse, mutect2, varscan2
- IRAK3 | c.1327C>G p.L443V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54159484, COSV54164983; called by muse, mutect2, varscan2
- IRX5 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58058445; called by muse, varscan2
- IRX5 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV58058451; called by muse, varscan2
- ITGAV | c.1046T>A p.L349Q | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53709372; called by muse, mutect2, varscan2
- KARS1 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as COSV56690693; called by muse, mutect2, varscan2
- KCNJ2 | c.219C>A p.F73L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV54660221; called by muse, mutect2, varscan2
- KDM6A | c.2066C>G p.S689* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as COSV100938704, COSV65045588; called by muse, mutect2, varscan2
- KEL | c.1637C>G p.S546C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV62333453; called by muse, mutect2, varscan2
- KHDRBS1 | c.763C>G p.L255V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV56980783, COSV56982543; called by muse, mutect2, varscan2
- KIAA1522 | c.577G>A p.D193N (on ENST00000373480 / NM_001198972.2; = p.D252N on NM_020888.3) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV53862499; called by muse, mutect2, varscan2
- KIF15 | c.2574G>C p.E858D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV58158620; called by muse, mutect2, varscan2
- KLK12 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV51575800; called by muse, mutect2, varscan2
- KMT2C | c.6691G>C p.E2231Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as COSV51311036, COSV51497826, COSV99030879; called by muse, mutect2, varscan2
- KMT2C | c.2453C>T p.S818L | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.829); catalogued as rs138111015, COSV99030793; called by muse, mutect2
- KMT2D | c.14336G>T p.G4779V | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV56413297; called by muse, mutect2, varscan2
- KRBOX4 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.275); catalogued as COSV53342877; called by muse, mutect2, varscan2
- LAMA4 | c.1372G>A p.E458K (on ENST00000230538 / NM_001105206.3; = p.E451K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.944); catalogued as COSV100039740; called by muse, mutect2
- LAMC1 | c.1933C>G p.Q645E | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV51133032; called by muse, mutect2, varscan2
- LIN54 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV61200179; called by muse, mutect2, varscan2
- LINGO3 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.011); catalogued as COSV68260977, COSV68261966; called by muse, mutect2, varscan2
- LSG1 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54568565; called by muse, mutect2, varscan2
- LSG1 | c.82C>G p.R28G | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.654); catalogued as COSV54568573, COSV54572161; called by muse, mutect2, varscan2
- MACF1 | c.15655G>T p.E5219* (on ENST00000372915; = p.E3152* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99247435; called by muse, mutect2, varscan2
- MAGEB10 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV63310442; called by muse, mutect2, varscan2
- MAGEB16 | c.296C>G p.S99* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as COSV101303348, COSV67874128; called by muse, mutect2, varscan2
- MCC | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as COSV56724320; called by muse, mutect2, varscan2
- MCM7 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV57994075; called by muse, mutect2, varscan2
- MECOM | c.983C>G p.S328* (on ENST00000468789 / NM_001105078.4; = p.S516* on NM_004991.4) | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV52971005, COSV99245760; called by muse, mutect2, varscan2
- MED21 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 32/64 reads (50%) | catalogued as COSV99282145; called by muse, mutect2, varscan2
- METTL25 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.138); catalogued as COSV50257640, COSV50261416; called by muse, mutect2, varscan2
- MEX3B | c.1517C>A p.S506Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV100314260; called by muse, mutect2
- MICAL2 | c.2579A>G p.N860S | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.027); catalogued as COSV56316836; called by muse, mutect2, varscan2
- MICALL2 | c.1761G>C p.W587C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV52514184; called by muse, mutect2, varscan2
- MST1R | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 27/86 reads (31%) | catalogued as COSV99619945; called by muse, mutect2, varscan2
- MYH10 | c.2727G>T p.M909I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV52595413, COSV52596343; called by muse, mutect2, varscan2
- MYO1A | c.2732C>T p.S911F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV55651950; called by muse, mutect2, varscan2
- MYORG | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52626303; called by muse, mutect2, varscan2
- NBAS | c.319C>A p.Q107K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV55713327; called by muse, mutect2, varscan2
- NBEA | c.3124G>C p.D1042H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV59762170; called by muse, mutect2, varscan2
- NBPF15 | c.1886G>A p.R629K | Missense Mutation (SNP) | VAF 78/312 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.114); catalogued as rs782505072; called by muse, mutect2, varscan2
- NCAPD3 | c.4423C>T p.P1475S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV54450428; called by muse, mutect2, varscan2
- NDRG2 | c.125C>G p.S42C (on ENST00000298687 / NM_001354570.1; = p.S28C on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV53871806, COSV53873440; called by muse, mutect2, varscan2
- NKAP | c.1062G>A p.M354I | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV65055956; called by muse, mutect2, varscan2
- NR2C2 | c.1166C>T p.S389F (on ENST00000393102; = p.S408F on NM_003298.5) | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60144834; called by muse, varscan2
- NR5A2 | c.1015C>G p.L339V (on ENST00000367362 / NM_205860.3; = p.L293V on NM_003822.5) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.035); catalogued as COSV52645414; called by muse, mutect2, varscan2
- NRCAM | c.1204G>T p.E402* (on ENST00000379028 / NM_001371124.1; = p.E396* on NM_005010.4 and 21 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100695757, COSV61048866; called by muse, mutect2, varscan2
- NSUN3 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV58934017; called by muse, mutect2, varscan2
- OBP2A | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV59790985; called by muse, mutect2, varscan2
- OBSCN | c.9339G>C p.L3113F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV52743581; called by muse, mutect2, varscan2
- OLFML1 | c.119G>C p.R40P | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.048); catalogued as COSV61402196; called by muse, mutect2, varscan2
- OR6M1 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58432815; called by muse, mutect2, varscan2
- OTUD4 | c.2335C>G p.Q779E (on ENST00000447906 / NM_001366057.1; = p.Q714E on NM_001102653.1) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV71381482; called by muse, mutect2, varscan2
- PALB2 | c.2336C>T p.S779L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as rs764509489, COSV55162590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PALB2 | c.2240C>G p.S747C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs1373451258, COSV55162606; ClinVar: uncertain significance; called by muse, varscan2
- PALB2 | c.1837C>T p.Q613* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV99849120; called by muse, mutect2, varscan2
- PALB2 | c.1745C>A p.S582Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV55162637; called by muse, mutect2, varscan2
- PCDHB10 | c.922G>C p.D308H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs782317669, COSV53375623; called by muse, mutect2, varscan2
- PCDHB4 | c.1799G>A p.W600* | Nonsense Mutation (SNP) | VAF 29/137 reads (21%) | catalogued as COSV52024153, COSV99522582; called by muse, mutect2, varscan2
- PCDHB5 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); catalogued as COSV50647436, COSV99039368; called by muse, mutect2, varscan2
- PCNT | c.5137G>A p.E1713K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV64025339; called by muse, mutect2, varscan2
- PDSS1 | c.769G>C p.A257P | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV66058375; called by muse, mutect2, varscan2
- PEAK1 | c.3100C>T p.H1034Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV56931181; called by muse, mutect2, varscan2
- PEAK1 | c.2989C>G p.Q997E | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV56931205; called by muse, mutect2, varscan2
- PEAK1 | c.2633C>T p.S878F | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56931224; called by muse, mutect2, varscan2
- PEAK1 | c.2156C>T p.S719L | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as COSV56931244; called by muse, mutect2, varscan2
- PEAK1 | c.1712C>T p.T571I | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56931263; called by muse, mutect2, varscan2
- PEG3 | c.4303G>A p.E1435K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV55625700; called by muse, mutect2, varscan2
- PEX12 | c.446C>G p.S149C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV56777599; called by muse, mutect2, varscan2
- PHLPP1 | c.4801G>T p.E1601* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99409534; called by muse, mutect2, varscan2
- PIK3CA | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV55884357, COSV55965142; called by muse, mutect2, varscan2
- PIKFYVE | c.4262C>T p.S1421L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.057); catalogued as COSV52237335; called by muse, mutect2, varscan2
- PITX3 | c.180G>C p.K60N | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs1310235570, COSV100892854; called by muse, mutect2, varscan2
- PKMYT1 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs368126121; called by muse, varscan2
- PKN3 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 34/57 reads (60%) | catalogued as COSV99404031; called by muse, mutect2, varscan2
- PLA2R1 | c.3649C>T p.R1217C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.87); catalogued as rs960101159, COSV51775202; called by muse, mutect2, varscan2
- PLEC | c.12634G>C p.E4212Q (on ENST00000322810 / NM_201380.4; = p.E4102Q on NM_000445.5) | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as COSV59605904; called by muse, mutect2, varscan2
- PLEKHG6 | c.1651C>T p.Q551* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99164840; called by muse, mutect2
- PLTP | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.364); catalogued as COSV62463863; called by muse, mutect2, varscan2
- PLVAP | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as COSV53083686; called by muse, mutect2, varscan2
- PLXNB1 | c.2282C>T p.P761L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56486833; called by muse, mutect2, varscan2
- PLXNB1 | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs767426005, COSV99603593; called by muse, mutect2, varscan2
- PPL | c.3868G>C p.E1290Q | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV52165919; called by muse, mutect2, varscan2
- PPP1R16B | c.549C>G p.I183M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV55374446, COSV55377968; called by muse, mutect2, varscan2
- PPP1R26 | c.1661G>A p.R554K | Missense Mutation (SNP) | VAF 80/150 reads (53%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV63354773; called by muse, mutect2, varscan2
- PRDM5 | c.813G>C p.K271N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53356256; called by muse, mutect2, varscan2
- PROSER1 | c.1402C>G p.L468V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.26); catalogued as COSV61486336; called by muse, mutect2, varscan2
- PRPF40A | c.2340G>A p.M780I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.346); catalogued as COSV68356211; called by muse, mutect2, varscan2
- PSPC1 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV58886721; called by muse, mutect2, varscan2
- PTPRO | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as COSV55503869; called by muse, varscan2
- PTPRO | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV55503880; called by muse, varscan2
- PYGO1 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1389657573, COSV57346650; called by muse, mutect2, varscan2
- RAB11B | c.431-1G>A p.X144_splice | Splice Site (SNP) | VAF 16/45 reads (36%) | catalogued as COSV60085257; called by muse, mutect2, varscan2
- RABIF | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs919986734, COSV66131345; called by muse, mutect2, varscan2
- RAC1 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV61821797, COSV61822724; called by muse, mutect2, varscan2
- RAF1 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52574933, COSV52583065; called by muse, mutect2, varscan2
- RAI14 | c.727C>G p.Q243E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as COSV54289722, COSV99461949; called by muse, mutect2, varscan2
- RAPGEF2 | c.2143C>G p.Q715E | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV52425039; called by muse, mutect2, varscan2
- RECK | c.1279C>G p.R427G | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV65034673, COSV65035887; called by muse, mutect2, varscan2
- RELA | c.927C>G p.F309L | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV58013883; called by muse, mutect2, varscan2
- RFX4 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as COSV67270434; called by muse, mutect2, varscan2
- RFX4 | c.1890C>G p.I630M (on ENST00000392842 / NM_213594.3; = p.I536M on NM_032491.6) | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); catalogued as COSV57572573; called by muse, mutect2, varscan2
- RHBDF1 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.3); catalogued as COSV51953603; called by muse, mutect2, varscan2
- RHOT2 | c.868C>T p.L290= | Splice Region (SNP) | VAF 24/89 reads (27%) | catalogued as rs1017983802, COSV53466711; called by muse, mutect2, varscan2
- RIPK1 | c.1911G>A p.M637I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs748199482, COSV52527985, COSV99454660; called by muse, mutect2, varscan2
- RNF17 | c.2244C>T p.I748= | Splice Region (SNP) | VAF 20/70 reads (29%) | catalogued as rs756925498, COSV55034577; called by muse, mutect2, varscan2
- RNF213 | c.11344G>T p.E3782* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100301695; called by muse, mutect2, varscan2
- RPGRIP1 | c.2791C>T p.P931S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs761644947, COSV52845326; called by muse, mutect2, varscan2
- RPN1 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV99957360; called by muse, mutect2, varscan2
- RTL1 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV66016423; called by muse, mutect2, varscan2
- S100A7A | c.192G>C p.K64N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV61329979; called by muse, mutect2, varscan2
- S1PR1 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1323297044, COSV59512624; called by muse, mutect2, varscan2
- SCN5A | c.4677C>G p.I1559M (on ENST00000333535 / NM_198056.3; = p.I1558M on NM_000335.5) | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as COSV61116648; called by muse, mutect2, varscan2
- SCNM1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV54859559; called by muse, mutect2, varscan2
- SETD2 | c.6964-1G>C p.X2322_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV57438724; called by muse, mutect2
- SFXN2 | c.227C>G p.S76W | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200250986, COSV64011838, COSV64012685; called by muse, mutect2, varscan2
- SGO1 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.141); catalogued as COSV55422883; called by muse, mutect2, varscan2
- SGPP2 | c.309C>G p.I103M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV58327250; called by muse, mutect2, varscan2
- SIGLEC10 | c.1870C>G p.L624V | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as rs368033766, COSV59482883; called by muse, mutect2, varscan2
- SLC2A7 | c.573C>G p.I191M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV68901334; called by muse, mutect2, varscan2
- SLC6A17 | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58991446; called by muse, mutect2, varscan2
- SLC9A1 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV56051251; called by muse, mutect2, varscan2
- SLCO1B3 | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV53932974, COSV99682392; called by muse, mutect2, varscan2
- SLIT2 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as rs1277021289, COSV56561268, COSV99884293; called by muse, mutect2, varscan2
- SMC1A | c.3399G>C p.K1133N | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59127838; called by muse, mutect2, varscan2
- SOX4 | c.329G>C p.R110P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV55192803; called by muse, mutect2
- SPTBN1 | c.3664G>C p.E1222Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.065); catalogued as COSV61685778; called by muse, mutect2, varscan2
- SSH2 | c.2309G>C p.G770A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as COSV52166948; called by muse, mutect2, varscan2
- SSRP1 | c.1943C>T p.S648L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV53478301; called by muse, mutect2, varscan2
- STAG2 | c.1502T>A p.L501* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as COSV99495729; called by muse, mutect2, varscan2
- STX16 | c.187G>C p.D63H (on ENST00000371141 / NM_001001433.3; = p.D42H on NM_003763.6) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56604368; called by muse, mutect2, varscan2
- SUCLA2 | c.1298G>T p.R433L (on ENST00000643023; = p.R412L on NM_003850.3) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV66221885; called by muse, mutect2, varscan2
- SVIL | c.3004G>C p.E1002Q (on ENST00000355867 / NM_021738.3; = p.E576Q on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as COSV63440112, COSV63449511; called by muse, mutect2, varscan2
- SYNE3 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs745629148, COSV62078021; called by muse, mutect2, varscan2
- TAF1L | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.01); catalogued as rs1261064270, COSV54256533; called by muse, mutect2, varscan2
- TENM3 | c.3710G>A p.R1237K | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV69299874, COSV69310840; called by muse, mutect2, varscan2
- TEP1 | c.7726G>C p.D2576H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV52988419; called by muse, mutect2, varscan2
- TET1 | c.3375G>C p.Q1125H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV65382253; called by muse, mutect2, varscan2
- TEX264 | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764083278, COSV56583272; called by muse, mutect2, varscan2
- TLN2 | c.6415G>A p.E2139K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV60885900; called by muse, mutect2, varscan2
- TMEM131L | c.2806C>T p.L936F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV53641435; called by muse, mutect2, varscan2
- TMEM201 | c.882G>C p.Q294H | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV61050897; called by muse, mutect2, varscan2
- TMEM33 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52561393; called by muse, varscan2
- TNPO1 | c.463-1G>A p.X155_splice | Splice Site (SNP) | VAF 5/29 reads (17%) | catalogued as COSV61520282; called by muse, mutect2, varscan2
- TRIM22 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV66090254; called by muse, mutect2, varscan2
- TRIM23 | c.1144C>A p.Q382K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.761); catalogued as COSV51549710; called by muse, mutect2, varscan2
- TRIM25 | c.1456C>G p.Q486E | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV57543312, COSV57543716; called by muse, mutect2, varscan2
- TRIM28 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.112); catalogued as COSV53398901; called by muse, mutect2, varscan2
- TRIP13 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs1053998000, COSV99386592; called by muse, mutect2
- TSPEAR | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1277378753, COSV59952918; called by muse, mutect2, varscan2
- TST | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as COSV50764850; called by muse, mutect2, varscan2
- TTC21A | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs1205695059, COSV57183197; called by muse, mutect2, varscan2
- TTN | c.83277G>C p.L27759F (on ENST00000591111; = p.L20335F on NM_003319.4) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | PolyPhen probably damaging (0.999); catalogued as COSV59901632; called by muse, mutect2, varscan2
- TTN | c.45499G>A p.D15167N (on ENST00000591111; = p.D7743N on NM_003319.4) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | PolyPhen probably damaging (0.964); catalogued as COSV59901650; called by muse, mutect2, varscan2
- TTYH1 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as rs1253348898, COSV100001799; called by muse, mutect2, varscan2
- TUBG1 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.079); catalogued as COSV52220572; called by muse, mutect2, varscan2
- UBE2C | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1258952908, COSV54754463, COSV54755051; called by muse, mutect2, varscan2
- UBLCP1 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV57142644; called by muse, mutect2, varscan2
- UBR5 | c.8400G>C p.*2800Yext*42 | Nonstop Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99642669; called by muse, mutect2
- UHRF1BP1 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV51952976; called by muse, mutect2, varscan2
- UNC45B | c.2280G>C p.E760D | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as rs1334672645, COSV52092552; called by muse, mutect2, varscan2
- USF3 | c.3568G>T p.E1190* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100325909, COSV57072060; called by muse, mutect2, varscan2
- USF3 | c.1931C>T p.S644L | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as COSV57070107; called by muse, mutect2, varscan2
- USP10 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.278); catalogued as COSV54747210; called by muse, mutect2, varscan2
- USP32 | c.3469C>G p.L1157V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56264472; called by muse, mutect2, varscan2
- VN1R1 | c.165G>C p.Q55H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58090763; called by muse, mutect2, varscan2
- VTI1B | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV53619114; called by muse, mutect2, varscan2
- ZAN | c.1931C>T p.S644L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as rs1249444138, COSV61805420; called by muse, mutect2, varscan2
- ZBED4 | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs1296556660, COSV53463847; called by muse, mutect2, varscan2
- ZC3HC1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as COSV61296995; called by muse, mutect2, varscan2
- ZFHX3 | c.11063C>A p.P3688H | Missense Mutation (SNP) | VAF 62/248 reads (25%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV51709617; called by muse, mutect2, varscan2
- ZIM3 | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as COSV54140182; called by muse, mutect2, varscan2
- ZKSCAN5 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); catalogued as rs570693286, COSV58741915; called by muse, mutect2, varscan2
- ZMYM4 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV58907244, COSV58910151; called by muse, mutect2, varscan2
- ZNF226 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV56195978; called by muse, mutect2, varscan2
- ZNF229 | c.1810G>A p.V604M | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs752215607, COSV52159867; called by muse, mutect2, varscan2
- ZNF282 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV50479121; called by muse, varscan2
- ZNF292 | c.3193C>G p.L1065V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV60535894; called by muse, mutect2
- ZNF425 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV65200604, COSV65202436; called by muse, mutect2, varscan2
- ZNF513 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV52006519; called by muse, mutect2, varscan2
- ZNF800 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.051); catalogued as rs1477997467, COSV56173825; called by muse, mutect2, varscan2
- ZNF800 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as rs565893361, COSV56173841; called by muse, mutect2, varscan2
- ZSCAN2 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57571871; called by muse, mutect2, varscan2
- NEUROD2 | c.1140dup p.H381Sfs*2 | Frame Shift Ins (INS) | VAF 7/15 reads (47%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCG4 | c.1881C>T p.F627= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs1162348079, COSV56642131; called by muse, varscan2
- ABHD16A | c.1275C>T p.I425= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV65451385; called by muse, varscan2
- ADAM19 | c.171G>A p.V57= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV57423336; called by muse, mutect2, varscan2
- ALPK3 | c.1356C>T p.L452= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV51930165; called by muse, mutect2, varscan2
- AMBRA1 | c.3762C>G p.V1254= (on ENST00000458649 / NM_001367468.1; = p.V1164= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV54049075, COSV54063227; called by muse, mutect2, varscan2
- AMPD2 | c.1890G>T p.L630= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs772396309, COSV56646281, COSV99857683; called by muse, mutect2, varscan2
- AMY1B | c.963C>T p.G321= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as rs563962104, COSV100375538; called by muse, mutect2, varscan2
- ATP12A | c.2952C>T p.L984= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV54512728; called by muse, mutect2, varscan2
- BPIFB3 | c.42C>G p.L14= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV64956848; called by muse, mutect2, varscan2
- CFAP251 | c.3213C>T p.F1071= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV56608123; called by muse, mutect2, varscan2
- CHD6 | c.1914C>T p.F638= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV58554113; called by muse, mutect2, varscan2
- CLRN3 | c.519G>A p.T173= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as rs550245323, COSV100899758, COSV64098188; called by muse, mutect2, varscan2
- CLUH | c.3711G>A p.L1237= (on ENST00000435359; = p.L1276= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV70927865; called by muse, mutect2, varscan2
- COL5A3 | c.5237G>A p.*1746= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV99319949; called by muse, mutect2, varscan2
- DAGLA | c.2760C>T p.L920= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV57194270; called by muse, mutect2, varscan2
- EIF2AK4 | c.402C>T p.L134= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as COSV55465372; called by muse, mutect2, varscan2
- FBXW4 | c.918G>A p.L306= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as COSV58706784; called by muse, mutect2, varscan2
- FO393400.1 | c.387G>C p.L129= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV54069563; called by muse, mutect2, varscan2
- FRMD5 | c.867G>A p.E289= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV68720474; called by muse, mutect2, varscan2
- GBX2 | c.576G>A p.P192= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs757987864, COSV60444902; called by muse, mutect2, varscan2
- GOLIM4 | c.111G>A p.Q37= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV58328025; called by muse, mutect2, varscan2
- GPER1 | c.912C>T p.L304= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV52467911; called by muse, mutect2, varscan2
- GPR88 | c.927C>T p.F309= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs541880945, COSV59291096; called by muse, mutect2, varscan2
- GSTA5 | c.156C>T p.F52= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV52861344; called by muse, mutect2, varscan2
- HSD11B1L | c.567C>T p.F189= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs749690063, COSV56797691; called by mutect2, varscan2
- HTT | c.1851C>T p.F617= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs977973605, COSV61857812; called by muse, mutect2, varscan2
- ICAM1 | c.936G>A p.A312= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as rs199692247; called by muse, mutect2, varscan2
- IL18RAP | c.720G>A p.V240= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs1264479674, COSV51824007; called by muse, mutect2, varscan2
- ITGAV | c.1045C>T p.L349= | Silent (SNP) | VAF 47/158 reads (30%) | catalogued as COSV53709345; called by muse, mutect2, varscan2
- ITIH3 | c.1704G>A p.E568= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV69647993; called by muse, mutect2, varscan2
- JAG1 | c.2823C>G p.L941= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as rs1251748794, COSV54753788; called by muse, mutect2, varscan2
- KAT2B | c.564C>T p.F188= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1316039734, COSV55426925; called by muse, mutect2, varscan2
- KCTD13 | c.810G>A p.E270= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV58156517; called by muse, mutect2, varscan2
- KDM4A | c.582C>G p.L194= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV64958842; called by muse, mutect2, varscan2
- KIF18A | c.1323G>A p.L441= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV54181331, COSV54183271; called by muse, mutect2, varscan2
- KIF20A | c.1272G>A p.L424= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV67509339; called by muse, mutect2, varscan2
- KIF26A | c.2442C>T p.F814= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs371265576; called by muse, mutect2
- KIF2C | c.1086C>T p.L362= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV64763965; called by muse, mutect2, varscan2
- KMT2C | c.13659C>T p.L4553= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs775094094, COSV51310840; called by muse, mutect2, varscan2
- KRT76 | c.1686C>T p.V562= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100196582; called by muse, mutect2
- LMO7 | c.1386C>G p.P462= (on ENST00000357063; = p.P192= on NM_015842.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV58530640; called by muse, mutect2, varscan2
- LPP | c.336G>A p.E112= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV57079920; called by muse, mutect2, varscan2
- LRRC56 | c.1188C>T p.L396= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1198951417, COSV54237736; called by muse, mutect2, varscan2
- LRRIQ4 | c.855C>G p.L285= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs776819147, COSV61618679; called by mutect2, varscan2
- MAP2K3 | c.378C>T p.F126= (on ENST00000342679 / NM_145109.3; = p.F97= on NM_002756.4) | Silent (SNP) | VAF 23/138 reads (17%) | catalogued as COSV57562299; called by muse, mutect2, varscan2
- MAP3K10 | c.1527C>T p.I509= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV53420548; called by muse, mutect2, varscan2
- MBTPS1 | c.3084G>A p.P1028= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs754896455, COSV58569480; called by muse, mutect2, varscan2
- MIP | c.375G>T p.V125= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV57514764, COSV99234487; called by muse, mutect2, varscan2
- MRPS17 | c.198C>T p.L66= | Silent (SNP) | VAF 52/188 reads (28%) | catalogued as rs373262300; called by muse, mutect2, varscan2
- NEURL1 | c.600C>G p.L200= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs762427333, COSV63913695; called by muse, mutect2, varscan2
- OBSL1 | c.2388C>T p.F796= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99217656; called by muse, mutect2
- OR10H2 | c.264C>G p.T88= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100008906; called by muse, mutect2, varscan2
- OR10J1 | c.898C>T p.L300= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV71128219, COSV71128490; called by muse, mutect2, varscan2
- OR51V1 | c.213C>T p.L71= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV58314191; called by muse, mutect2, varscan2
- OXCT1 | c.12C>G p.L4= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV52167561; called by muse, mutect2, varscan2
- PCARE | c.3471G>A p.G1157= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV59053179; called by muse, mutect2, varscan2
- PCARE | c.2232G>C p.L744= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV59053190; called by muse, mutect2, varscan2
- PFKP | c.1719C>T p.T573= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV66889899, COSV66890580; called by muse, mutect2, varscan2
- PHLPP2 | c.1455C>G p.L485= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV62422711; called by muse, mutect2, varscan2
- PKN3 | c.816G>A p.V272= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as COSV52574957; called by muse, mutect2, varscan2
- PPP6R3 | c.1497C>T p.F499= (on ENST00000393800 / NM_001352375.2; = p.F448= on NM_018312.5) | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV55721756; called by muse, mutect2, varscan2
- PTGIS | c.1155C>A p.L385= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV54835069, COSV54838781; called by muse, varscan2
- PTGIS | c.1047C>G p.L349= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV54835084, COSV54838389; called by muse, varscan2
- PTH1R | c.1134C>T p.F378= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV57314628; called by muse, mutect2, varscan2
- PTPRN2 | c.2676G>A p.L892= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV101153396; called by muse, mutect2, varscan2
- RNF123 | c.2319C>T p.S773= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV59684501; called by muse, mutect2, varscan2
- ROCK1 | c.3291C>T p.L1097= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV67694610; called by muse, mutect2, varscan2
- RTP5 | c.888C>T p.L296= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV58319043; called by muse, mutect2, varscan2
- SAP30BP | c.22C>T p.L8= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1029021417, COSV53126791; called by muse, mutect2, varscan2
- SEC63 | c.78C>T p.I26= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs763743900, COSV64598662; called by muse, mutect2, varscan2
- SPG21 | c.429C>T p.F143= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV52602134; called by muse, mutect2, varscan2
- SPOPL | c.1110C>T p.A370= | Silent (SNP) | VAF 58/271 reads (21%) | catalogued as COSV54512015; called by muse, mutect2, varscan2
- SPTBN2 | c.6855C>G p.V2285= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as COSV59447414; called by muse, mutect2, varscan2
- SSC4D | c.729C>T p.F243= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV51881362, COSV51884787; called by muse, mutect2, varscan2
- STX1B | c.561G>A p.T187= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs763651481, COSV52679684; called by muse, mutect2, varscan2
- STYK1 | c.570C>T p.L190= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs758168434, COSV50012361; called by muse, mutect2, varscan2
- TAF5L | c.813G>A p.L271= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV51077426; called by muse, mutect2, varscan2
- TG | c.6987C>T p.I2329= | Silent (SNP) | VAF 22/172 reads (13%) | catalogued as rs140927008; called by muse, mutect2, varscan2
- TIE1 | c.1911G>A p.V637= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV65248560; called by muse, mutect2, varscan2
- TIRAP | c.579C>T p.F193= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV67023812; called by muse, mutect2
- TM4SF19 | c.60G>C p.L20= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV56556221; called by muse, mutect2, varscan2
- TMEM131 | c.5214C>T p.F1738= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as rs752716349, COSV51770571; called by muse, mutect2, varscan2
- TRIM63 | c.735C>T p.L245= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV65327774; called by muse, varscan2
- TRIM63 | c.657C>T p.I219= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as COSV65327779; called by muse, varscan2
- TUBD1 | c.603C>T p.L201= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs200063088; called by muse, mutect2, varscan2
- UBE2D3 | c.9G>A p.L3= | Silent (SNP) | VAF 43/129 reads (33%) | catalogued as COSV57660534; called by muse, mutect2, varscan2
- UCK2 | c.420C>T p.F140= | Silent (SNP) | VAF 68/206 reads (33%) | catalogued as COSV63314426; called by muse, mutect2, varscan2
- UNG | c.267C>T p.N89= (on ENST00000242576 / NM_080911.3; = p.N80= on NM_003362.4) | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as rs757301291, COSV54356666; called by muse, mutect2, varscan2
- USPL1 | c.1620C>G p.A540= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV54998745; called by muse, mutect2, varscan2
- ZSCAN2 | c.1581G>A p.E527= | Silent (SNP) | VAF 37/155 reads (24%) | catalogued as rs1284760641, COSV57571874; called by muse, mutect2, varscan2
- ZWILCH | c.975G>A p.L325= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV57178367; called by muse, mutect2, varscan2
- AC116366.2 | c.-671G>C | 5'UTR (SNP) | VAF 10/32 reads (31%) | catalogued as COSV61819024; called by muse, mutect2, varscan2
- AMDHD2 | c.*1511C>A | 3'UTR (SNP) | VAF 6/24 reads (25%) | catalogued as COSV53551721; called by muse, mutect2, varscan2
- PKM | c.1141-418C>G | Intron (SNP) | VAF 10/65 reads (15%) | catalogued as COSV58787049; called by muse, mutect2, varscan2
- SNORD3B-2 | n.211G>C | RNA (SNP) | VAF 11/169 reads (7%) | catalogued as rs758442077; called by muse, varscan2
- SNORD3B-2 | n.162G>T | RNA (SNP) | VAF 16/182 reads (9%) | catalogued as rs374142989; called by muse, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 5/34 reads (15%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2
